Gene-level copy-number profile of tumor specimen TCGA-HC-A9TH-01A from TCGA case TCGA-HC-A9TH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.8 years (21,460 days).
Specimen TCGA-HC-A9TH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.d23b92d4-7bfe-4c9e-8461-8011f8df5e8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-A9TH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ca5073a-c5c8-4f9b-99c1-46df3fd2a39d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 6,301; copy number 2: 53,109; copy number 3: 348.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-A9TH-01A-11D-A41J-01): tumor purity 0.7, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,395,187–88,259,372, 59 genes: AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
